Gene-level copy-number profile of tumor specimen TCGA-G9-6496-01A from TCGA case TCGA-G9-6496, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.9 years (22,602 days).
Specimen TCGA-G9-6496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.bcbd830a-af25-4ec2-8797-767a2b4148e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G9-6496-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8d690e03-5d53-4890-8189-f5a693554446

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,621; copy number 2: 52,570; copy number 3: 442; copy number 5: 360; copy number 6: 27; copy number 7: 352; copy number 8: 443.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G9-6496-01A-11D-1785-01): tumor purity 0.83, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,182 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:13,854,355–33,877,180, 346 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:35,695,214–42,706,447, 116 genes, copy number 7 (broad region; genes not listed).
- chr7:47,252,139–47,661,648, 4 genes, copy number 7: AC087175.1, TNS3, LINC01447, C7orf65.
- chr7:47,761,476–47,766,772, 1 gene, copy number 7: LINC00525.
- chr7:86,216,785–89,496,918, 38 genes, copy number 5–8: SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1.
- chr7:91,264,433–92,917,187, 32 genes, copy number 5–8: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr7:93,424,486–93,574,730, 1 gene, copy number 8 (within-gene range 3–8): CALCR.
- chr7:93,591,573–100,867,010, 209 genes, copy number 5–8 (broad region; genes not listed).
- chr7:101,362,875–101,559,024, 1 gene, copy number 5 (within-gene range 3–5): COL26A1.
- chr7:101,562,779–104,208,047, 70 genes, copy number 5–8 (broad region; genes not listed).
- chr7:132,123,332–132,648,688, 1 gene, copy number 5 (within-gene range 3–5): PLXNA4.
- chr7:132,352,334–146,050,366, 361 genes, copy number 5–8 (broad region; genes not listed).
- chr7:146,208,665–146,311,822, 2 genes, copy number 7: AC073418.1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 3,241. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
